Gene-level copy-number profile of tumor specimen CDDP-A8B0-TTP1-C from CDDP_EAGLE case CDDP-A8B0, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 66 years.
Specimen CDDP-A8B0-TTP1-C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6dc249d0-d841-4a58-9731-20350fc04023.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-A8B0-NC1-A (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,864 have no estimate.
https://portal.gdc.cancer.gov/files/d4128b7b-c0f1-4c4d-9972-55fd0bd0be43

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 1,967; copy number 2: 4,632; copy number 3: 9,416; copy number 4: 25,562; copy number 5: 10,477; copy number 6: 3,259; copy number 7: 1,139; copy number 8: 897; copy number 9: 545; copy number 10: 490; copy number 11: 346.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:587,629–594,768, 1 gene (within-gene range 0–6): AC114498.1.
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–4): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr4:49,548,564–49,589,529, 7 genes: AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr15:19,878,555–19,973,218, 7 genes: AC138701.1, RNU6-978P, AC138701.2, AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2.
- chr19:43,153,279–43,269,530, 5 genes: AC005392.1, PSG5, PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,381 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:57,392,546–145,066,685, 1,322 genes, copy number 9–11 (broad region; genes not listed).
- chr10:3,748,966–3,834,728, 4 genes, copy number 9: AL450322.2, AL450322.1, KLF6, LINC02639.
- chr10:63,167,221–65,880,289, 24 genes, copy number 9–11: JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1, AC013287.1, RPL7AP50, AC012558.1, DBF4P1, RPL17P35, CYP2C61P, ANXA2P3, LINC02671, NEK4P3, MYL6P3, AL513321.1, AL592466.1, LINC01515.
- chr11:85,957,175–86,196,266, 4 genes, copy number 9: PICALM, RNU6-560P, LINC02695, FNTAP1.
- chr12:37,575,587–37,576,384, 1 gene, copy number 11: ZNF970P.
- chr16:57,358,783–58,000,453, 26 genes, copy number 9 (within-gene range 5–9): CCL22, CX3CL1, CCL17, CIAPIN1, COQ9, AC009052.1, POLR2C, DOK4, CCDC102A, ADGRG5, HMGB3P32, ADGRG1, AC018552.3, ADGRG3, AC018552.2, DRC7, AC018552.1, KATNB1, KIFC3, AC092118.2, MIR6772, AC092118.1, RNU6-20P, CNGB1, TEPP, ZNF319.

Autosomal genes at a single copy (total copy number 1): 899. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
